Somatic mutation profile of tumor specimen TARGET-20-PASVFG-03A (aliquot TARGET-20-PASVFG-03A-01D) from TARGET case TARGET-20-PASVFG, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.2 years (5,195 days).
Specimen TARGET-20-PASVFG-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f59e1321-c6f8-481a-8570-a092f959f7e0.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASVFG-14A (Bone Marrow Normal), aliquot TARGET-20-PASVFG-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a762498b-47a5-418b-a86a-045ab9a2c735

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 83/272 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CEBPA | c.914dup p.R306Afs*15 | Frame Shift Ins (INS) | VAF 56/143 reads (39%) | catalogued as COSV57198163, COSV57198564, COSV57198672, COSV57199528; called by mutect2, pindel, varscan2
- GATA2 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 87/191 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1420609104, CM141457, COSV62005311; called by muse, mutect2, varscan2
- STAG2 | c.1968del p.Q656Hfs*2 | Frame Shift Del (DEL) | VAF 54/134 reads (40%) | called by mutect2, pindel, varscan2
